Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3387, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3387-01A (Primary Tumor).

[page 1 of 2]
CGA-A3-3387

Sex: Male

PHYSICIAN INFORMATION

SPECIMEN INFO

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Kidney, left, nephrectomy:

Tumor Characteristics:

1. Histologic type: Clear cell (conventional) renal cell adenocarcinoma.
2. Tumor site: Upper pole.
3. Tumor size: 4.0 x 4.0 x 2.5 cm.
4. Macroscopic extent of tumor: Tumor limited to kidney.
5. Nuclear grade: Fuhrman grade: 2/4.
6. Lymphovascular space invasion: Present.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not resected.

Surgical Margin Status:

1. Soft tissue margins: Negative.
2. Ureteral margin: Negative.
3. Vascular Margins: Negative.

Lymph Node Status:

1. Total number of lymph nodes examined: 0

Other Significant Findings:

2. pTNM stage: T1a NX MX

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

[page 2 of 2]
GROSS DESCRIPTION:

The specimen is received in one container labeled [REDACTED] and left kidney and consists of a previously bisected kidney with attached perinephric fat measuring 25.0 x 15.0 x 7.5 cm and weighs 930 grams. There is no adrenal gland attached to the specimen. The ureter stump is identified measuring 6.0 cm in length and 0.4 cm in diameter. The surface is gray to brown-tan with slight adhesions. On opening the mucosal surface lining the ureter is gray-tan. There are no lesions seen grossly. The renal artery stump is identified measuring 2.5 cm in length and 0.5 cm in diameter and contains clotted blood, but is otherwise unremarkable. The renal vein stump measures 0.7 cm in length and 0.5 cm in diameter and is grossly unremarkable. The deep margin of the kidney has been inked. The cut surface of the kidney is brown-tan and reveals a circumscribed golden yellow partially hemorrhagic mass within the upper pole measuring 4.0 x 4.0 x 2.5 cm that on sectioning comes to within 0.1 cm of the inked deep margin, but does not appear to penetrate through the capsule into the surrounding perinephric fat. The surrounding renal cortex is brown-tan measuring 0.5 cm and shows a well demarcated cortex and renal pyramids. The renal pelvis and calices are gray-tan and uninvolved by the mass and appear grossly unremarkable. There are no other lesions seen grossly. On sectioning through the surrounding perinephric fat reveals there are no lymph nodes grossly identified. Representative sections were taken for genomic studies and placed in orange cassettes labeled A-D. Also received with the specimen are two cassettes, one green and one yellow, labeled [REDACTED]. Representative sections are submitted in cassettes [REDACTED] as follows: sections from mass in relationship to inked deep margin—1 to 3; additional sections from mass and surrounding kidney—4 and 5; sections from surrounding uninvolved kidney—6; ureter margin—7; renal artery and vein—8.

Source: NCI Genomic Data Commons file b82be4e6-12c3-4c53-b82f-5b90c5ea6990 (TCGA-A3-3387.F5199278-AA10-477E-A9A8-000ED52065AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).